Somatic mutation profile of tumor specimen TCGA-5R-AAAM-01A (aliquot TCGA-5R-AAAM-01A-12D-A40R-10) from TCGA case TCGA-5R-AAAM, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.8 years (24,020 days).
Specimen TCGA-5R-AAAM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1601a162-1f67-4d18-8354-10ba7d0627d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5R-AAAM-10A (Blood Derived Normal), aliquot TCGA-5R-AAAM-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d57c0d1-c504-414e-828f-d0b9ed465562

The open-access MAF lists 86 somatic variants for this specimen: 66 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 19, Nonsense Mutation 6, Frame Shift Del 3, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXO1 | c.65C>G p.S22W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV65426970; called by muse, mutect2, varscan2
- NFE2L2 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960012, COSV67960020, COSV67960088; called by muse, mutect2, varscan2
- ACAP2 | c.908A>T p.K303M | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100461319; called by muse, mutect2
- ANO6 | c.2237C>T p.T746M | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746237936, COSV100262096; called by muse, mutect2, varscan2
- ARMC4 | c.2096A>G p.Q699R | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100536191; called by muse, mutect2, varscan2
- ASIC3 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.318); catalogued as COSV99873606; called by mutect2, varscan2
- C5orf51 | c.548T>G p.L183* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV101068831; called by muse, mutect2, varscan2
- C7orf25 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100623585; called by muse, mutect2
- CARD6 | c.1205A>C p.Q402P | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV99620068; called by muse, mutect2, varscan2
- CCDC181 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100890228; called by muse, mutect2
- CD1B | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100939119, COSV63805379; called by muse, mutect2
- CHIA | c.216T>G p.N72K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.399); catalogued as COSV100588537; called by muse, mutect2, varscan2
- CNBP | c.417-1G>A p.X139_splice | Splice Site (SNP) | VAF 13/104 reads (13%) | catalogued as COSV101421432; called by muse, mutect2, varscan2
- CYFIP2 | c.3755C>A p.S1252Y (on ENST00000616178 / NM_001291722.2; = p.S1227Y on NM_014376.4) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.202); catalogued as COSV100555471, COSV59041633; called by muse, mutect2, varscan2
- DOK5 | c.742A>G p.M248V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs1451527471, COSV99373127; called by muse, mutect2
- ENPP2 | c.2390C>G p.P797R (on ENST00000075322 / NM_001040092.3; = p.P849R on NM_006209.5) | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99030202, COSV99307301; called by muse, mutect2, varscan2
- EPHA2 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV100626004; called by muse, mutect2, varscan2
- FBXO17 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV53069430, COSV99493865; called by muse, mutect2
- FGB | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100122279; called by muse, mutect2, varscan2
- GIMAP1 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV100211899; called by muse, mutect2, varscan2
- GPR18 | c.688T>C p.S230P | Missense Mutation (SNP) | VAF 5/123 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100540495; called by muse, mutect2
- GRM7 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63129838; called by muse, mutect2, varscan2
- HSPA8 | c.1265C>A p.T422N | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); catalogued as COSV57084001, COSV99914140; called by muse, mutect2, varscan2
- IGKV3-7 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs369766180; called by muse, mutect2, varscan2
- INSR | c.3716G>A p.G1239D | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100251225; called by muse, mutect2, varscan2
- KMT2B | c.5590C>T p.R1864* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as COSV55856587; called by muse, mutect2, varscan2
- LMNTD1 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV99279277; called by muse, mutect2, varscan2
- LRCH2 | c.2051A>G p.H684R | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1556526449, COSV100406137; called by muse, mutect2, varscan2
- MGAT5B | c.1754C>T p.A585V (on ENST00000569840 / NM_001199172.2; = p.A583V on NM_144677.3) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs199872537, COSV56934974; called by muse, mutect2, varscan2
- MKRN3 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100090586; called by muse, mutect2, varscan2
- NR5A2 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 50/181 reads (28%) | catalogued as rs537463980, COSV52649763; called by muse, mutect2, varscan2
- ODAM | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV101258015; called by muse, mutect2
- OR5F1 | c.492C>A p.S164R | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99558338; called by muse, mutect2, varscan2
- PATJ | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100332947; called by muse, mutect2
- PAX3 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100398905; called by muse, mutect2, varscan2
- PCDHB6 | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV50699597, COSV99169894; called by muse, mutect2, varscan2
- PCDHGA5 | c.1778C>A p.A593E | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1179892338, COSV99529124; called by muse, mutect2, varscan2
- PDE8B | c.2573T>A p.M858K | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99365984; called by muse, mutect2
- PKHD1 | c.11727C>G p.I3909M | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100943405; called by muse, mutect2, varscan2
- RNASE6 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100485890; called by muse, mutect2, varscan2
- RPL21 | c.277A>C p.I93L | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as COSV55388190, COSV99699206; called by muse, mutect2, varscan2
- SEC24D | c.2575C>G p.P859A | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99755277; called by muse, mutect2, varscan2
- SLC25A31 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as rs773420489, COSV55419202; called by muse, mutect2, varscan2
- SPTA1 | c.6676G>A p.A2226T | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.679); catalogued as rs766070401, COSV63749098, COSV63750709; called by muse, mutect2, varscan2
- SPTA1 | c.983A>G p.E328G | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100934092; called by muse, mutect2
- SUGCT | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.405); catalogued as COSV99999359; called by muse, mutect2, varscan2
- TCF20 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as COSV100166178; called by muse, mutect2, varscan2
- TENM1 | c.7685A>G p.N2562S | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV100948865; called by muse, mutect2
- TENT4A | c.2138C>A p.P713H | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.944); catalogued as COSV100048531, COSV50103903; called by muse, mutect2
- TNC | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100404792; called by muse, mutect2, varscan2
- TOP3B | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs752975410, COSV100592271; called by muse, mutect2, varscan2
- TRDN | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV100520630; called by muse, mutect2, varscan2
- TTN | c.69349C>T p.Q23117* (on ENST00000591111; = p.Q15693* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as COSV100591401; called by muse, mutect2, varscan2
- USH2A | c.13226C>T p.S4409F | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); catalogued as rs752003063, COSV56415746; called by muse, mutect2, varscan2
- VPS13B | c.2785A>G p.I929V | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1222718209, COSV100660636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VTI1A | c.350A>T p.H117L | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV101260945; called by muse, mutect2, varscan2
- VWF | c.2581C>T p.H861Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1185601519, COSV54633817; called by muse, mutect2, varscan2
- Z83844.2 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100378969; called by muse, mutect2
- ZNF687 | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100133829, COSV100134303; called by muse, mutect2, varscan2
- ZNF835 | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1247110613, COSV101606245; called by muse, mutect2, varscan2
- CDC42BPA | c.3397dup p.V1133Gfs*3 (on ENST00000334218 / NM_001366019.2; = p.V1120Gfs*3 on NM_003607.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- HEATR9 | c.1436T>C p.L479P | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- LILRB3 | c.1184G>T p.R395M | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NAV2 | c.7229del p.P2410Lfs*38 (on ENST00000396087 / NM_001244963.2; = p.P2351Lfs*38 on NM_145117.5) | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- PAPLN | c.2547_2592del p.K850Gfs*99 (on ENST00000554301; = p.K823Gfs*99 on NM_173462.4) | Frame Shift Del (DEL) | VAF 22/148 reads (15%) | called by mutect2, pindel
- STBD1 | c.1033_1072del p.G345Tfs*12 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel
- ATG16L1 | c.459T>C p.C153= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV100731237; called by mutect2, varscan2
- ATP1A4 | c.541C>A p.R181= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV100927432; called by muse, mutect2, varscan2
- BRWD3 | c.2307A>G p.P769= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100955591; called by muse, mutect2, varscan2
- CACNA1F | c.5085C>T p.P1695= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV100544293; called by muse, mutect2, varscan2
- CCT6B | c.930A>C p.I310= | Silent (SNP) | VAF 11/165 reads (7%) | catalogued as COSV100030395; called by muse, mutect2
- EDN3 | c.138T>C p.C46= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV100284712; called by muse, mutect2, varscan2
- H3C12 | c.366T>G p.P122= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV100377432; called by muse, mutect2, varscan2
- IRGQ | c.1797C>T p.G599= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100338034; called by muse, mutect2, varscan2
- MYBL1 | c.1893T>C p.N631= | Silent (SNP) | VAF 56/142 reads (39%) | catalogued as COSV72918827; called by muse, mutect2, varscan2
- MYO5A | c.4035C>T p.A1345= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV100697217, COSV100697932; called by muse, mutect2, varscan2
- NHS | c.1467A>G p.E489= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV101196346; called by muse, mutect2, varscan2
- NPHP3 | c.1665G>T p.L555= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV58627807; called by muse, mutect2
- PLXNA3 | c.721C>T p.L241= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100859785; called by muse, mutect2, varscan2
- ROR2 | c.1137G>A p.T379= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs767456619, COSV65216122; called by muse, mutect2, varscan2
- SLCO5A1 | c.927A>T p.G309= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV99479247; called by muse, mutect2, varscan2
- TCF20 | c.345G>T p.V115= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as COSV100166181; called by muse, mutect2, varscan2
- TTLL9 | c.633G>A p.Q211= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV100206178; called by muse, mutect2
- USP10 | c.315T>C p.T105= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV99551041; called by muse, mutect2, varscan2
- WDR19 | c.1746C>T p.Y582= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs539697450, COSV56471488; called by muse, mutect2, varscan2
- LINC02877 | n.571T>C | RNA (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
